Somatic mutation profile of cancer-model specimen HCM-CSHL-0078-C25-85B (3D Organoid; aliquot HCM-CSHL-0078-C25-85B-01D-A78M-36), derived from the primary tumor of HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f763c1c6-6e06-4ee9-b60a-985bbc42e663.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0078-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0078-C25-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37b4ad3b-7212-4fab-8209-2fea5b1bce4a

The open-access MAF lists 143 somatic variants for this specimen: 94 protein-altering or splice-affecting, 29 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 29, RNA 5, Frame Shift Del 5, 5'UTR 4, Intron 4, 3'UTR 3, Nonsense Mutation 2, 5'Flank 2, 3'Flank 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 390/390 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATF | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs368531596; called by muse, mutect2, varscan2
- AC011462.1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 113/391 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs374369488; called by muse, mutect2, varscan2
- ADNP | c.3062G>C p.G1021A | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs1237911024; called by muse, mutect2, varscan2
- BCAS3 | c.1969G>A p.V657I (on ENST00000390652 / NM_001353144.2; = p.V642I on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.093); catalogued as rs766648044; called by muse, varscan2
- BRCA2 | c.5590G>C p.D1864H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as CM1111063; called by muse, mutect2, varscan2
- C2orf50 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV101059477; called by muse, mutect2, varscan2
- CADM2 | c.242G>A p.R81H (on ENST00000407528 / NM_001167674.2; = p.R83H on NM_153184.4) | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs778733322, CM145841, COSV67385719, COSV67414308; called by muse, mutect2, varscan2
- CDC5L | c.2332C>G p.Q778E | Missense Mutation (SNP) | VAF 240/285 reads (84%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs756396867; called by muse, mutect2, varscan2
- DOK2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 123/267 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs766198984; called by muse, mutect2, varscan2
- ENKUR | c.469T>C p.Y157H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777986119; called by muse, mutect2, varscan2
- EPPK1 | c.4487C>T p.A1496V | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.242); catalogued as rs782143817; called by muse, mutect2, varscan2
- FBXO15 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs202075662, COSV99077190; called by muse, mutect2, varscan2
- GABRD | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as rs1259972227; called by muse, mutect2, varscan2
- GFPT1 | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV100622996; called by muse, mutect2, varscan2
- HOXD12 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1216506512, COSV101184276; called by muse, mutect2, varscan2
- HRNR | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 215/1240 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769962080, COSV64256820; called by muse, mutect2, varscan2
- IL16 | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 31/345 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57263860; called by muse, mutect2
- LAMA5 | c.778C>A p.R260S | Missense Mutation (SNP) | VAF 145/442 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53362723; called by muse, mutect2, varscan2
- LAMC2 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 127/268 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV51456248; called by muse, mutect2, varscan2
- LPA | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 138/390 reads (35%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.98); catalogued as rs1170862921, COSV60303792; called by muse, mutect2, varscan2
- MINDY4 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs370104814; called by muse, mutect2, varscan2
- MSC | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV57696960; called by muse, mutect2, varscan2
- OR4M1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 156/364 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100270969, COSV60060509; called by mutect2, varscan2
- OXNAD1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1389018393, COSV53265982; called by muse, mutect2, varscan2
- PALM | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs372771354; called by muse, mutect2, varscan2
- POLR1E | c.1046G>A p.R349Q (on ENST00000377792 / NM_001282766.1; = p.R287Q on NM_022490.4) | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as rs745330508, COSV66773064; called by muse, mutect2, varscan2
- PRAMEF27 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 213/527 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174375626; called by muse, mutect2, varscan2
- RDH13 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV52562435; called by muse, mutect2
- RGS3 | c.3392C>T p.A1131V (on ENST00000350696 / NM_001282923.2; = p.A850V on NM_130795.4) | Missense Mutation (SNP) | VAF 79/124 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs144334750; called by muse, mutect2, varscan2
- SSTR4 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs372339309; called by muse, mutect2, varscan2
- TMEM91 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as rs1032654429, COSV99652565; called by muse, mutect2, varscan2
- UACA | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 134/136 reads (99%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778220594; called by mutect2, varscan2
- USP6NL | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs781289702, COSV53209782; called by muse, mutect2, varscan2
- VEPH1 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 171/259 reads (66%) | catalogued as COSV62882192; called by muse, mutect2, varscan2
- ZFHX4 | c.6683C>T p.S2228F | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99256741; called by muse, mutect2, varscan2
- ZNF146 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs759214480, COSV104422226; called by muse, mutect2, varscan2
- ZNF536 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 152/220 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180623012, COSV62818669; called by muse, mutect2, varscan2
- ZNF585B | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV57216139; called by muse, mutect2, varscan2
- ADCY10 | c.3682A>G p.K1228E | Missense Mutation (SNP) | VAF 102/1063 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADGRL3 | c.4396A>G p.S1466G (on ENST00000506720 / NM_001322402.2; = p.S1355G on NM_015236.6) | Missense Mutation (SNP) | VAF 128/231 reads (55%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- APC2 | c.6221G>C p.R2074P | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ARFGEF3 | c.2435G>C p.S812T | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP22 | c.741G>T p.R247S | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- ARPIN | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH23 | c.6472G>A p.A2158T | Missense Mutation (SNP) | VAF 360/549 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CEACAM18 | c.968G>C p.C323S | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD7 | c.6605del p.E2202Gfs*13 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | called by mutect2, pindel, varscan2
- COG3 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DDX31 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNASE1L1 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 160/160 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DNASE2 | c.141_142del p.G48Afs*49 | Frame Shift Del (DEL) | VAF 102/442 reads (23%) | called by pindel, varscan2
- FAM169A | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FLG | c.1599G>T p.E533D | Missense Mutation (SNP) | VAF 208/1241 reads (17%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FOXC1 | c.18dup p.V7Rfs*76 | Frame Shift Ins (INS) | VAF 29/41 reads (71%) | called by mutect2, pindel, varscan2
- FRMD6 | c.1043A>G p.E348G (on ENST00000344768 / NM_001267046.2; = p.E340G on NM_152330.4) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- GAL3ST1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 255/256 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HECA | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KDM5C | c.1503_1519del p.W501Cfs*10 | Frame Shift Del (DEL) | VAF 94/109 reads (86%) | called by mutect2, pindel, varscan2
- L3MBTL4 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LPIN2 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 112/391 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED13 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH5 | c.2816G>C p.S939T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.466); called by muse, mutect2
- MUC6 | c.6589_6590del p.L2197Ffs*12 | Frame Shift Del (DEL) | VAF 60/182 reads (33%) | called by pindel, varscan2
- NEB | c.16955A>G p.Y5652C | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51C1P | c.830C>G p.A277G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OR5H14 | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- OTOG | c.7977G>T p.E2659D | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PDE6B | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PHF12 | c.1885C>G p.P629A | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- POGLUT3 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PPP3CA | c.731C>G p.T244S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPN13 | c.7224C>A p.C2408* (on ENST00000411767 / NM_080683.3; = p.C2389* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 98/188 reads (52%) | called by muse, mutect2, varscan2
- RABGAP1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RBM26 | c.1303C>G p.P435A | Missense Mutation (SNP) | VAF 89/171 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIOK2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SAMD8 | c.204A>T p.L68F | Missense Mutation (SNP) | VAF 114/170 reads (67%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SCAF1 | c.2437G>C p.V813L | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SCN2A | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 128/578 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SH3BP4 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC5A8 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 50/62 reads (81%) | called by pindel, varscan2
- TANC1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 228/317 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TENT2 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TMEM121 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMEM237 | c.874G>T p.D292Y (on ENST00000409883 / NM_001044385.3; = p.D284Y on NM_152388.4) | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNKS | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTN | c.31510C>G p.P10504A (on ENST00000591111; = p.P9577A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/227 reads (19%) | PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TXLNG | c.1520G>C p.S507T | Missense Mutation (SNP) | VAF 63/63 reads (100%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WDR62 | c.77del p.P26Rfs*51 | Frame Shift Del (DEL) | VAF 82/271 reads (30%) | called by mutect2, pindel, varscan2
- WNK2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 388/630 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XRCC4 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZFHX2 | c.6059G>C p.S2020T | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF202 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ZNF502 | c.1279A>G p.R427G | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ACKR1 | c.1005A>G p.K335= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs765926244; called by muse, varscan2
- ADAMTSL4 | c.1377C>T p.P459= | Silent (SNP) | VAF 284/1543 reads (18%) | catalogued as rs779949072, COSV55000365; called by muse, mutect2, varscan2
- AGBL4 | c.450T>C p.F150= | Silent (SNP) | VAF 88/183 reads (48%) | called by muse, mutect2, varscan2
- ATG4B | c.222C>T p.C74= | Silent (SNP) | VAF 87/376 reads (23%) | called by muse, mutect2, varscan2
- CCDC24 | c.204T>A p.S68= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- CERKL | c.1233A>G p.K411= (on ENST00000339098 / NM_001030311.2; = p.K385= on NM_201548.5) | Silent (SNP) | VAF 172/708 reads (24%) | called by muse, mutect2, varscan2
- CLSTN2 | c.696G>T p.L232= | Silent (SNP) | VAF 177/285 reads (62%) | called by muse, mutect2, varscan2
- DPF2 | c.432C>T p.G144= | Silent (SNP) | VAF 95/192 reads (49%) | catalogued as COSV52888870; called by muse, mutect2, varscan2
- ELOA2 | c.1182G>A p.K394= | Silent (SNP) | VAF 124/378 reads (33%) | called by muse, mutect2, varscan2
- EVC2 | c.3615C>T p.S1205= | Silent (SNP) | VAF 189/422 reads (45%) | called by muse, mutect2, varscan2
- FLG | c.7242C>T p.F2414= | Silent (SNP) | VAF 284/1088 reads (26%) | called by muse, mutect2, varscan2
- GNAT1 | c.435C>T p.N145= | Silent (SNP) | VAF 135/421 reads (32%) | catalogued as rs749785058; called by muse, mutect2, varscan2
- IRX3 | c.1473C>T p.A491= | Silent (SNP) | VAF 166/265 reads (63%) | called by muse, mutect2, varscan2
- KIF1A | c.3438C>G p.A1146= | Silent (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- MED23 | c.1296C>A p.L432= | Silent (SNP) | VAF 100/233 reads (43%) | called by muse, mutect2, varscan2
- NEB | c.10305G>A p.P3435= | Silent (SNP) | VAF 113/470 reads (24%) | catalogued as rs528974814, COSV99415147; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXMIF | c.1749C>T p.P583= | Silent (SNP) | VAF 86/86 reads (100%) | called by muse, mutect2, varscan2
- NPC1L1 | c.927C>T p.P309= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs1017546573, COSV56922987; called by muse, mutect2, varscan2
- OBSCN | c.5016G>A p.V1672= | Silent (SNP) | VAF 196/397 reads (49%) | catalogued as COSV99486630; called by muse, mutect2, varscan2
- PGM5 | c.1566C>T p.Y522= | Silent (SNP) | VAF 80/260 reads (31%) | catalogued as rs782534536, COSV67166795; called by muse, mutect2, varscan2
- RBM25 | c.462G>A p.E154= | Silent (SNP) | VAF 52/168 reads (31%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.1080C>T p.D360= | Silent (SNP) | VAF 132/387 reads (34%) | catalogued as rs199568188, COSV57789870; called by muse, mutect2, varscan2
- TIE1 | c.2826T>C p.A942= | Silent (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- TNRC18 | c.5952G>A p.A1984= | Silent (SNP) | VAF 121/468 reads (26%) | catalogued as rs778246311; called by muse, mutect2
- TSPAN5 | c.606T>C p.Y202= | Silent (SNP) | VAF 75/169 reads (44%) | catalogued as rs760214816; called by muse, mutect2, varscan2
- UBR4 | c.11199G>A p.K3733= | Silent (SNP) | VAF 4/96 reads (4%) | catalogued as rs1450920224; called by muse, mutect2
- VPS13D | c.4890G>A p.Q1630= | Silent (SNP) | VAF 76/171 reads (44%) | called by muse, mutect2, varscan2
- ZCCHC4 | c.501G>A p.K167= | Silent (SNP) | VAF 10/324 reads (3%) | catalogued as COSV57180901; called by muse, mutect2
- ZNF556 | c.15C>A p.V5= | Silent (SNP) | VAF 67/200 reads (34%) | called by muse, mutect2, varscan2
- AC006305.1 | n.825A>G | RNA (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- ACBD4 | chr17:45143641 G>A | 3'Flank (SNP) | VAF 39/73 reads (53%) | called by muse, varscan2
- ARHGAP40 | c.-45C>T | 5'UTR (SNP) | VAF 25/206 reads (12%) | catalogued as rs779659523; called by muse, mutect2, varscan2
- CLEC17A | c.647-50G>A | Intron (SNP) | VAF 70/293 reads (24%) | called by muse, mutect2, varscan2
- DSTN | c.-84G>T | 5'UTR (SNP) | VAF 50/187 reads (27%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+325T>C | Intron (SNP) | VAF 97/835 reads (12%) | called by muse, mutect2, varscan2
- FAM161A | c.*1279T>C | 3'UTR (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- GPNMB | c.541+30C>A | Intron (SNP) | VAF 194/389 reads (50%) | called by muse, mutect2, varscan2
- HADH | chr4:107989882 C>G | 5'Flank (SNP) | VAF 78/178 reads (44%) | catalogued as rs536959577, COSV100531279, COSV58848862; called by muse, mutect2, varscan2
- HAUS7 | chrX:153470957 T>A | 5'Flank (SNP) | VAF 73/76 reads (96%) | called by muse, mutect2, varscan2
- IL12RB1 | c.*21del | 3'UTR (DEL) | VAF 66/289 reads (23%) | called by mutect2, pindel, varscan2
- LINC00602 | n.592C>A | RNA (SNP) | VAF 120/273 reads (44%) | catalogued as rs969920362; called by muse, mutect2, varscan2
- LINC01193 | n.1330C>A | RNA (SNP) | VAF 68/445 reads (15%) | called by muse, mutect2, varscan2
- LINC01956 | n.430G>C | RNA (SNP) | VAF 47/167 reads (28%) | catalogued as rs748304106; called by muse, mutect2, varscan2
- OPRM1 | c.-64A>G | 5'UTR (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- PADI4 | c.-2C>T | 5'UTR (SNP) | VAF 78/156 reads (50%) | catalogued as rs200461292; called by muse, mutect2, varscan2
- PYCARD | c.275-76del | Intron (DEL) | VAF 52/189 reads (28%) | called by mutect2, pindel, varscan2
- VMP1 | c.*1440C>A | 3'UTR (SNP) | VAF 27/47 reads (57%) | called by muse, mutect2, varscan2
- WASHC3 | chr12:102011836 G>A | 3'Flank (SNP) | VAF 82/189 reads (43%) | catalogued as rs1212203202; called by muse, mutect2, varscan2
- ZNF137P | n.1385A>G | RNA (SNP) | VAF 38/111 reads (34%) | catalogued as rs377386229; called by muse, mutect2, varscan2
